Gene-level copy-number profile of tumor specimen AP-7GDN-VP from APOLLO case AP-7GDN, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2.
Specimen AP-7GDN-VP: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f64a4493-d4de-451f-9872-f71414441c9c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-7GDN-BM (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/13f9945c-c133-4c87-a876-d84ef45a2a50

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 10; copy number 2: 8,118; copy number 3: 2,473; copy number 4: 40,044; copy number 5: 2,102; copy number 6: 2,195; copy number 7: 1,626; copy number 8: 1,548; copy number 9: 108; copy number 10: 6; copy number 11: 74; copy number 12: 603; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 792 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,573,747–160,262,549, 107 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr1:161,581,339–161,678,654, 6 genes, copy number 10 (within-gene range 8–10): FCGR2C, HSPA7, RPS23P9, FCGR3B, FCGR2B, AL451067.1.
- chr5:58,198–45,895,970, 679 genes, copy number 9–15 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
